HCMI case HCM-BROD-0643-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1c54d889-a752-4025-90ce-af896cdb95d4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1964; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 53.6 years (19,588 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: T4b; AJCC pathologic N: N3c; AJCC pathologic M: M1c; AJCC pathologic stage: Stage IV; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Nivolumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,104 days (3.0 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 54.7 years (19,965 days); Days to diagnosis: 377 days (1.0 years); Satellite nodule present: Indeterminate.
   Pathology details: Breslow thickness category: >4.0 mm; Lymph nodes positive: 3; Lymph nodes tested: 10.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Nivolumab; Treatment intent type: Maintenance Therapy; Treatment outcome: Treatment Ongoing.

Follow-up (2 entries)
- Days to follow up: 1,104 days (3.0 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 649.

Molecular and laboratory tests
- BRAF (IHC): Negative; Amino-acid change: V600E.
- BRAF mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 68 kg; Height: 170 cm; BMI: 23.5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0643-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0643-C43-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 20; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 77; Percent lymphocyte infiltration: 28; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0643-C43-06A-01-S1-HE: Section location: Top; Percent tumor cells: 54; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 6; Percent stromal cells: 40; Percent lymphocyte infiltration: 35; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0643-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0643-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 10.
